Somatic mutation profile of tumor specimen MMRF_1605_1_BM_CD138pos (aliquot MMRF_1605_1_BM_CD138pos_T1_KBS5U_L04121) from MMRF case MMRF_1605, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.5 years (17,365 days).
Specimen MMRF_1605_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 352d5be1-c3dd-4b2b-88ab-527207338812.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1605_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1605_1_PB_Whole_C2_KBS5U_L04127; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c79848a-cbdc-4bb3-9ef9-59979539f7bd

The open-access MAF lists 75 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 19, Silent 13, Intron 7, 5'UTR 4, 3'Flank 4, Nonsense Mutation 2, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPSF1 | c.2642C>G p.S881C | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs1158604993, COSV58235803; called by muse, mutect2, varscan2
- EPHB4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs142009811; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV100438456; called by muse, mutect2, varscan2
- HLTF | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1234343390; called by muse, mutect2, varscan2
- IGKJ5 | c.33G>T p.E11D | Missense Mutation (SNP) | VAF 104/238 reads (44%) | catalogued as rs142632901; called by muse, varscan2
- KRT1 | c.698C>A p.S233* | Nonsense Mutation (SNP) | VAF 48/100 reads (48%) | catalogued as CM060296; called by muse, mutect2, varscan2
- PADI1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs142259163; called by muse, mutect2, varscan2
- TTN | c.13999G>A p.V4667M (on ENST00000591111; = p.V3740M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | PolyPhen possibly damaging (0.743); catalogued as rs903648091; called by muse, mutect2, varscan2
- ZNF131 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 34/426 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs373229883; called by muse, mutect2
- ADAMTS2 | c.952A>T p.I318F | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CDH18 | c.804T>G p.F268L | Missense Mutation (SNP) | VAF 114/168 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- COL14A1 | c.968T>C p.M323T | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2
- CPSF2 | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- DNAJC5 | c.149A>G p.N50S | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- FASTKD3 | c.1454T>G p.L485W | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- IQCE | c.158A>C p.K53T | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- MAGEE1 | c.1196G>C p.G399A | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2
- MAP2K7 | c.641T>A p.I214N | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- MIA3 | c.5510C>G p.P1837R | Missense Mutation (SNP) | VAF 98/208 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- NFE2L1 | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 87/267 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- NR1H4 | c.953del p.K318Sfs*17 (on ENST00000551379 / NM_001206993.2; = p.K304Sfs*17 on NM_005123.4) | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- PCDHGA2 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RBP3 | c.1683G>A p.W561* | Nonsense Mutation (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- SETDB2 | c.1753A>T p.I585F | Missense Mutation (SNP) | VAF 89/97 reads (92%) | SIFT tolerated (0.14); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- TMUB2 | c.403G>C p.E135Q (on ENST00000538716 / NM_001353177.2; = p.E115Q on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/222 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TP53I13 | c.971T>A p.L324H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAF3 | c.1021del p.R341Gfs*10 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, varscan2
- CST2 | c.291C>T p.S97= | Silent (SNP) | VAF 13/159 reads (8%) | called by muse, mutect2
- DSG3 | c.891C>T p.Y297= | Silent (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2, varscan2
- DTHD1 | c.1848C>T p.T616= (on ENST00000456874; = p.T451= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/145 reads (53%) | called by muse, mutect2, varscan2
- HHATL | c.264A>G p.K88= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as rs913745816; called by muse, mutect2, varscan2
- HLTF | c.786A>T p.P262= | Silent (SNP) | VAF 38/101 reads (38%) | called by muse, mutect2, varscan2
- LINGO2 | c.1521T>C p.R507= | Silent (SNP) | VAF 86/191 reads (45%) | called by muse, mutect2, varscan2
- LRP1B | c.4788C>T p.F1596= | Silent (SNP) | VAF 77/179 reads (43%) | called by muse, mutect2, varscan2
- RIPOR2 | c.1458C>T p.S486= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- SLC7A7 | c.441C>T p.L147= | Silent (SNP) | VAF 50/59 reads (85%) | called by muse, mutect2
- SPEF2 | c.90T>C p.S30= | Silent (SNP) | VAF 213/319 reads (67%) | called by muse, mutect2, varscan2
- SYNCRIP | c.948T>C p.N316= | Silent (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- TBC1D20 | c.1110G>A p.L370= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.370C>T p.L124= | Silent (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- ALPP | c.*1054A>G | 3'UTR (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- AR | c.*2435T>G | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2
- ARFGEF2 | c.-69G>A | 5'UTR (SNP) | VAF 3/48 reads (6%) | catalogued as rs1568682478; called by muse, mutect2
- BCL7A | chr12:122021570 C>T | 5'Flank (SNP) | VAF 33/61 reads (54%) | catalogued as rs551915100, COSV55848051; called by muse, mutect2, varscan2
- CACNA1E | c.*5964G>A | 3'UTR (SNP) | VAF 46/114 reads (40%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65883743 A>C | 3'Flank (SNP) | VAF 52/103 reads (50%) | called by muse, mutect2, varscan2
- CEP78 | c.*1983G>A | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- CLDN9 | c.*446A>G | 3'UTR (SNP) | VAF 121/292 reads (41%) | catalogued as rs781736331; called by muse, mutect2, varscan2
- CNOT7 | c.*1396G>T | 3'UTR (SNP) | VAF 100/129 reads (78%) | called by muse, mutect2, varscan2
- CNOT7 | c.*1395G>A | 3'UTR (SNP) | VAF 100/129 reads (78%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+562G>A | Intron (SNP) | VAF 32/70 reads (46%) | catalogued as rs1355683074; called by muse, mutect2, varscan2
- DDX25 | c.*2645C>T | 3'UTR (SNP) | VAF 30/188 reads (16%) | catalogued as rs1409161084; called by muse, mutect2, varscan2
- DENND10 | c.-9del | 5'UTR (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- DNAH14 | c.3051+15036G>T | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- EIF3I | c.-5C>T | 5'UTR (SNP) | VAF 37/285 reads (13%) | catalogued as rs1306094040; called by muse, mutect2, varscan2
- FAF2 | c.*2380del | 3'UTR (DEL) | VAF 69/135 reads (51%) | called by mutect2, pindel, varscan2
- FGL1 | c.-17-124G>A | Intron (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- H2AZ1 | c.326-33C>T | Intron (SNP) | VAF 5/134 reads (4%) | called by muse, mutect2
- IRAK3 | c.*3588C>T | 3'UTR (SNP) | VAF 39/86 reads (45%) | called by muse, mutect2, varscan2
- KCNE4 | c.*651del | 3'UTR (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- KIF13A | chr6:17759557 C>A | 3'Flank (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- MANEA | c.*348C>T | 3'UTR (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- MINDY2 | c.*1857C>T | 3'UTR (SNP) | VAF 273/575 reads (47%) | called by muse, mutect2, varscan2
- NAP1L3 | c.*390A>G | 3'UTR (SNP) | VAF 57/59 reads (97%) | catalogued as rs886072294; called by muse, mutect2, varscan2
- NEBL | c.*4584T>C | 3'UTR (SNP) | VAF 5/109 reads (5%) | called by muse, mutect2
- NOC2L | c.179+10G>A | Intron (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- OOSP3 | chr11:59898368 C>T | 3'Flank (SNP) | VAF 39/298 reads (13%) | catalogued as rs902722639; called by muse, mutect2, varscan2
- PEG3 | c.*4C>T | 3'UTR (SNP) | VAF 49/109 reads (45%) | called by muse, mutect2, varscan2
- RASGRP2 | c.-71-1027A>G | Intron (SNP) | VAF 147/339 reads (43%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20318328 C>G | 3'Flank (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- TCF7L2 | c.*948A>G | 3'UTR (SNP) | VAF 65/139 reads (47%) | catalogued as rs935036732; called by muse, mutect2, varscan2
- TOMM20 | c.*169T>G | 3'UTR (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- TYR | c.-27G>A | 5'UTR (SNP) | VAF 16/40 reads (40%) | catalogued as rs1406673459; called by muse, mutect2, varscan2
- USP42 | c.442+1181G>C | Intron (SNP) | VAF 29/264 reads (11%) | called by muse, mutect2, varscan2
- XPNPEP3 | c.*5806A>G | 3'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
